Gene-level copy-number profile of specimen HCM-CSHL-0174-C22-85A from HCMI case HCM-CSHL-0174-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 64.9 years (23,717 days).
Specimen HCM-CSHL-0174-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04860c6f-7bdc-46fd-a550-2f1d0d1a68b8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0174-C22-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/84a7ca05-57a6-4f8a-8a65-754a13dc990e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 9,186; copy number 2: 46,413; copy number 3: 2,802.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:184,712,245–184,740,104, 1 gene: AC107294.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,186. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
